Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3AK, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3AK-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: total thyroid, level 6 neck dissection, stitch mark right superior pole

Diagnosis

1. Multifocal papillary carcinoma, dominant 2.0 cm classical variant left: Thyroid
No pathological diagnosis: Lymph nodes, 2, isthmus
-Total thyroidectomy specimen.

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	4.5 cm
	2.4 cm
	1.2 cm
	Left lobe:
	4.0 cm
	2.4 cm
	1.7 cm
	Isthmus +/- pyramidal lobe:
	4.6 cm
	1.4 cm
	0.6 cm
Specimen Weight:	14.5 g
Tumor Focality:	Multifocal, bilateral
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 2.0cm
	Additional dimension: 1.8 cm
	Additional dimension: 1.4 cm

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
10/21/11

[page 2 of 2]
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, other variant: focal hobnail change (<5% of tumor).
Classical (papillary) architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Present, extent minimal
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
-----SECOND TUMOR-----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 0.2cm
Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: None
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 2
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Other: additional papillary microcarcinomas identified in right lobe (0.05, 0.05cm) and in left lobe (0.1cm).

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

The specimen labeled with the patient's name and as "Thyroid: Total thyroid, level 6 neck dissection, stitch marks right superior pole" consists of a thyroid gland that is oriented with a stitch and weighs 14.5 g. The right lobe measures 4.5 cm SI x 2.4 cm ML x 1.2 cm AP, the left lobe measures 4.0 cm SI x 2.4 cm ML x 1.7 cm AP and the isthmus measures 4.6 cm SI x 1.4 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or lymph nodes are identified grossly. No central compartment is identified. The upper left lobe contains a well delineated nodule that measures 2.0 cm SI x 1.8 cm ML x 1.4 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of left lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-E right lobe, superior to inferior
1F-G isthmus
1H-N left lobe, superior to inferior

Source: NCI Genomic Data Commons file 1680d788-49b5-472a-8f84-45a0c4555627 (TCGA-EM-A3AK.8A05B9C2-42A1-4200-8EB9-8BA20242B7C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).